Somatic mutation profile of tumor specimen TCGA-BG-A221-01A (aliquot TCGA-BG-A221-01A-21D-A159-09) from TCGA case TCGA-BG-A221, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 84.8 years (30,960 days).
Specimen TCGA-BG-A221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a97f3fce-2d60-4be0-a863-0c560af244d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A221-10A (Blood Derived Normal), aliquot TCGA-BG-A221-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/964b710d-2259-48bc-8e07-5e812f107779

The open-access MAF lists 1,415 somatic variants for this specimen: 1,024 protein-altering or splice-affecting, 355 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 752, Silent 355, Frame Shift Del 172, Nonsense Mutation 30, Splice Site 26, Frame Shift Ins 20, Intron 14, RNA 14, In Frame Del 11, Splice Region 11, 3'UTR 3, 5'UTR 3.

Variants (750 of 1,415; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.900del p.G301Vfs*19 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs1555067335; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- DDX3X | c.1592C>T p.T531M (on ENST00000399959; = p.T532M on NM_001356.5) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795387, COSV67863875; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.5647C>T p.R1883* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs575017579, CM091928, COSV54240661; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.4379dup p.N1460Kfs*2 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs387906455; ClinVar: pathogenic; called by mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LDLR | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs755154048, CM061090, COSV99369612; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MLH1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs63751711, CM045463, CM082944, CS951471, CS961616, COSV51619014; ClinVar: pathogenic; called by muse, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TRDN | c.568dup p.I190Nfs*2 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs1085307100; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- A1BG | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs533605370, COSV54050119; called by muse, mutect2, varscan2
- AATF | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs989774289; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs749943218; called by mutect2, varscan2
- ACAP1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs757840962, COSV99341454; called by muse, mutect2, varscan2
- ACBD5 | c.662T>C p.M221T (on ENST00000375888 / NM_001352568.1; = p.M212T on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV101022488, COSV65518741; called by muse, mutect2
- ACE | c.3512T>C p.M1171T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99326500; called by muse, mutect2
- ACOT9 | c.906+2T>C p.X302_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100321205; called by muse, mutect2, varscan2
- ACTL6B | c.695dup p.N233Kfs*17 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs779550102; called by mutect2, varscan2
- ADAM11 | c.1699T>C p.C567R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99567148; called by muse, mutect2, varscan2
- ADAM7 | c.1781dup p.L594Ffs*4 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs756064662; called by mutect2, varscan2
- ADAMTS12 | c.4001A>G p.Y1334C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs751108294, COSV100710358; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV101001379; called by muse, mutect2, varscan2
- ADCK1 | c.1313T>C p.L438P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451114; called by muse, mutect2, varscan2
- ADCY1 | c.2605G>A p.V869I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs751469911, COSV99811368; called by muse, mutect2, varscan2
- ADGRE2 | c.322del p.T108Hfs*57 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | catalogued as COSV100215887; called by mutect2, varscan2
- ADGRF3 | c.376G>A p.V126I (on ENST00000311519 / NM_001145168.1; = p.V67I on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs757218422, COSV61049939; called by muse, mutect2, varscan2
- ADGRG4 | c.2580G>T p.E860D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99794502; called by muse, mutect2
- ADGRV1 | c.18595A>G p.T6199A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101315536; called by muse, mutect2, varscan2
- ADH1B | c.580T>C p.S194P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100520648; called by muse, mutect2
- AFDN | c.5380C>T p.R1794C (on ENST00000447894 / NM_001366320.1; = p.R1713C on NM_001207008.1) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100652537; called by muse, mutect2, varscan2
- AFM | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs778849064, COSV99888526; called by muse, mutect2, varscan2
- AGK | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100814544; called by muse, mutect2, varscan2
- AGPS | c.351G>A p.R117= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99931070; called by muse, mutect2, varscan2
- AHNAK2 | c.9340G>A p.E3114K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs777759148; called by mutect2, varscan2
- AHNAK2 | c.7470G>A p.M2490I | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as rs370718666, COSV100315886; called by muse, mutect2, varscan2
- AHNAK2 | c.3743A>C p.K1248T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100315888; called by muse, mutect2, varscan2
- AJM1 | c.122A>C p.E41A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99915472; called by muse, mutect2, varscan2
- AKAP1 | c.2499A>G p.S833= | Splice Region (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100532669; called by muse, mutect2, varscan2
- AKAP11 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99213571; called by muse, mutect2, varscan2
- AKAP7 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs557843005, COSV100818757; called by muse, mutect2, varscan2
- AKT3 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV99794339; called by muse, mutect2
- ALB | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99890851; called by muse, mutect2
- ALDH18A1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764145947, COSV64662460; called by muse, mutect2, varscan2
- ALDH1A3 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs750607041, COSV100320256; called by muse, mutect2, varscan2
- ALOX5 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as rs201769753, COSV100979973; called by muse, mutect2, varscan2
- AMPD3 | c.1427T>A p.I476N (on ENST00000396553 / NM_001025389.2; = p.I485N on NM_000480.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67332886; called by muse, mutect2, varscan2
- AMY2A | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs749935390, COSV70214501; called by muse, mutect2, varscan2
- ANAPC7 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as rs760487546, COSV101482842; called by mutect2, varscan2
- ANK2 | c.11319-2A>G p.X3773_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100000005; called by muse, mutect2, varscan2
- ANKRD1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs746392266, COSV65468067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKZF1 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs751709088, COSV55477570; called by muse, mutect2, varscan2
- ANO9 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100240780; called by muse, mutect2, varscan2
- ANO9 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs200422652, COSV60450101; called by muse, mutect2, varscan2
- ANTXR2 | c.87del p.L30Cfs*45 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs748892926; called by mutect2, varscan2
- AP1M1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.631); catalogued as rs1207571821, COSV52225084; called by muse, mutect2, varscan2
- AP1M2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1383931855, COSV51569372; called by muse, mutect2, varscan2
- AP3D1 | c.2424-2A>G p.X808_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100642406; called by muse, mutect2, varscan2
- APOB | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780817600, COSV51931789; ClinVar: likely benign; called by muse, mutect2, varscan2
- AQP5 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99527412; called by muse, mutect2
- ARFGEF2 | c.4213G>A p.A1405T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.738); catalogued as rs1430999905, COSV64211737, COSV64213292; called by muse, mutect2
- ARHGAP17 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV99252940; called by muse, mutect2, varscan2
- ARHGAP25 | c.42A>C p.K14N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV99771125; called by muse, mutect2, varscan2
- ARHGAP4 | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100603866; called by muse, mutect2
- ARHGEF10 | c.3133G>A p.A1045T (on ENST00000398564; = p.A1020T on NM_014629.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as rs989992745, COSV100033970; called by muse, mutect2, varscan2
- ARHGEF12 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100754691; called by muse, mutect2
- ARHGEF17 | c.4256T>C p.L1419P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99734961; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 5/43 reads (12%) | catalogued as rs1415146710; called by pindel, varscan2
- ARMC3 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1205306819, COSV53068649, COSV99957546; called by muse, mutect2
- ARMH4 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs367838185; called by muse, mutect2, varscan2
- ARNT | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490240303, COSV100590925, COSV62229602; called by muse, mutect2, varscan2
- ARNT2 | c.1492A>T p.M498L | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100308635; called by muse, mutect2, varscan2
- ARRDC1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100603536; called by muse, mutect2, varscan2
- ARSK | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV101187512; called by muse, mutect2, varscan2
- ARV1 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs972050503, COSV100048300; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs772181094; called by mutect2, varscan2
- ASB10 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775064026, COSV51998277; called by muse, mutect2, varscan2
- ATAD3A | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1023182167, COSV100186095; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAT1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs746108286, COSV99527748; called by mutect2, varscan2
- ATG2B | c.5590G>A p.V1864I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs778385045, COSV55891370; called by muse, varscan2
- ATM | c.7331A>C p.E2444A | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs879254245, COSV99587630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8131G>T p.E2711* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99587634; called by muse, mutect2, varscan2
- ATP13A5 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as rs759636595, COSV100664791; called by mutect2, varscan2
- ATP2C2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99297519; called by muse, mutect2, varscan2
- ATP7A | c.2734A>G p.T912A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1250703588, COSV100430305; called by muse, mutect2
- B4GALT5 | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV100866924; called by muse, mutect2
- BAAT | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV99408379; called by muse, mutect2, varscan2
- BCL7C | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV53062846; called by muse, mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs758526156; called by mutect2, pindel, varscan2
- BCL9L | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762653904, COSV52688581; called by muse, mutect2, varscan2
- BCL9L | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as COSV100599596; called by muse, mutect2, varscan2
- BCLAF1 | c.1828G>A p.V610M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100786405, COSV100786938; called by muse, mutect2, varscan2
- BCR | c.2744T>C p.V915A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1328058055, COSV100006042, COSV59934713; called by muse, mutect2, varscan2
- BIRC6 | c.12470C>T p.S4157F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101427921; called by muse, mutect2, varscan2
- BMP7 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1183761358, COSV101215577; called by muse, mutect2, varscan2
- BNIP5 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.179); catalogued as rs576970172, COSV71325557; called by muse, mutect2, varscan2
- BRICD5 | c.52-2A>G p.X18_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | catalogued as rs140372678; called by muse, mutect2, varscan2
- BRINP1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762030572, COSV99774601; called by muse, mutect2, varscan2
- BRSK1 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58666488; called by muse, mutect2, varscan2
- BRSK2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs747715851, COSV57546342; called by muse, mutect2, varscan2
- BTBD10 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as rs200899824, COSV99533382; called by muse, mutect2, varscan2
- BUB1 | c.1692A>C p.K564N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.372); catalogued as COSV57064482; called by muse, mutect2, varscan2
- C12orf40 | c.1324T>C p.S442P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV100209683; called by muse, mutect2
- C17orf97 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs372971711, COSV64076375; called by muse, varscan2
- C19orf47 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs369171913; called by muse, varscan2
- C19orf53 | c.151_153del p.K51del | In Frame Del (DEL) | VAF 9/50 reads (18%) | catalogued as rs1157325817; called by pindel, varscan2
- C1QTNF3 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.134); catalogued as rs551906960, COSV51468315; called by muse, mutect2, varscan2
- C7orf57 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100817203; called by muse, mutect2, varscan2
- C9orf50 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100992304; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACNA1A | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100801176; called by muse, mutect2, varscan2
- CACNA1A | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100801177; called by muse, mutect2, varscan2
- CACNA1D | c.3518G>A p.R1173H (on ENST00000350061 / NM_001128840.3; = p.R1193H on NM_000720.4) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756577309, COSV55459878; called by muse, mutect2, varscan2
- CACNA1G | c.3955G>A p.A1319T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs60231077, COSV61721524; called by muse, mutect2, varscan2
- CACNA1H | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.137); catalogued as rs752978426, COSV100670993; called by mutect2, varscan2
- CACNA2D4 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201084922, COSV54948461; called by muse, mutect2, varscan2
- CACNA2D4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as rs954675574, COSV54957789; called by muse, mutect2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA1 | c.4767del p.K1589Nfs*33 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs754008719; called by mutect2, varscan2
- CAPN11 | c.1012T>C p.W338R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291848; called by muse, mutect2, varscan2
- CAPN13 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs751792504, COSV54429237; called by muse, mutect2, varscan2
- CAPN5 | c.1700C>T p.A567V (on ENST00000456580; = p.A527V on NM_004055.5) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs868994232, COSV99581802; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARF | c.897dup p.V300Sfs*3 | Frame Shift Ins (INS) | VAF 7/21 reads (33%) | catalogued as rs751635415; called by mutect2, varscan2
- CARMIL3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs757377104, COSV53742395; called by muse, mutect2, varscan2
- CASP8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748087575, COSV51847309; called by muse, mutect2, varscan2
- CASZ1 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100680817; called by muse, mutect2, varscan2
- CATSPER1 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.111); catalogued as rs928590431, COSV100375670; called by muse, mutect2
- CBLB | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99912785; called by muse, mutect2, varscan2
- CC2D1A | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100528287; called by muse, mutect2, varscan2
- CC2D1B | c.788G>A p.S263N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99429697; called by muse, mutect2, varscan2
- CCDC116 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as rs144432807; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC88B | c.3428G>A p.R1143H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs368874751; called by muse, mutect2, varscan2
- CCDC97 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.325); catalogued as rs776032328, COSV99523626; called by muse, mutect2, varscan2
- CCT5 | c.1225A>G p.I409V | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99725133; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD40LG | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV101033434; called by muse, mutect2, varscan2
- CD59 | c.184A>G p.N62D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV100681137; called by muse, mutect2, varscan2
- CDH2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs750540712, COSV52286869; called by muse, mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs1367432489; called by mutect2, pindel, varscan2
- CDK4 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.54); catalogued as COSV99225887; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs753353408; called by mutect2, varscan2
- CDKL3 | c.886A>G p.M296V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99527639; called by muse, mutect2
- CDON | c.2896T>C p.Y966H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99700708; called by muse, mutect2, varscan2
- CELSR1 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV53093993; called by muse, mutect2, varscan2
- CELSR3 | c.8764C>T p.R2922C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1325146260, COSV99372702; called by muse, mutect2, varscan2
- CENPI | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs765434241, COSV54502988; called by muse, mutect2, varscan2
- CENPN | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100001136; called by muse, mutect2, varscan2
- CEP131 | c.1193-2A>G p.X398_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV53956872, COSV99487886; called by muse, mutect2, varscan2
- CEP164 | c.1724+1G>A p.X575_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as rs1489883516, COSV99632652; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.815); catalogued as rs754390813, COSV99267232; called by muse, mutect2, varscan2
- CFAP47 | c.4816C>T p.P1606S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV57975441; called by muse, mutect2
- CFAP61 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99843513; called by muse, mutect2, varscan2
- CFTR | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1368033715, COSV99134299; ClinVar: uncertain significance; called by muse, mutect2
- CHAF1A | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100010874; called by muse, mutect2, varscan2
- CHAT | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs141881680, COSV60334982; called by muse, mutect2, varscan2
- CHD7 | c.5206A>G p.N1736D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101418027; called by muse, mutect2, varscan2
- CHDH | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1394454363, COSV100179586; called by muse, mutect2, varscan2
- CHKB | c.582G>A p.R194= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs1346797803, COSV100376510; called by muse, mutect2, varscan2
- CHRNB3 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.058); catalogued as rs770336239, COSV99250913; called by muse, mutect2, varscan2
- CHST5 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as rs1212274563, COSV100291760; called by muse, mutect2, varscan2
- CKAP2 | c.1780G>A p.V594M (on ENST00000378037 / NM_001098525.2; = p.V593M on NM_018204.5) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs1260678684, COSV99318078; called by muse, mutect2
- CLCN2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs757494232, COSV99658258; called by muse, mutect2, varscan2
- CLDN16 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289991; called by muse, mutect2, varscan2
- CLEC16A | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs774312800, COSV68499663; called by mutect2, varscan2
- CLK3 | c.1600A>G p.M534V (on ENST00000395066 / NM_001130028.1; = p.M386V on NM_003992.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV59341261; called by muse, mutect2, varscan2
- CLTC | c.2543A>G p.E848G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV99291785; called by muse, mutect2, varscan2
- CNTNAP3 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs546554958, COSV52675068; called by muse, mutect2, varscan2
- CNTRL | c.4294C>T p.R1432C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1564284774, COSV99441271; called by muse, mutect2, varscan2
- COIL | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99538006; called by muse, mutect2, varscan2
- COL11A2 | c.4558C>T p.R1520C (on ENST00000341947 / NM_080680.3; = p.R1413C on NM_080679.2) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs934714603, COSV59494192; called by muse, mutect2, varscan2
- COL22A1 | c.4346C>T p.P1449L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746435872, COSV100276593; called by muse, mutect2, varscan2
- COL22A1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57339170; called by muse, mutect2, varscan2
- COL4A6 | c.1830del p.G611Afs*127 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | catalogued as rs771066852; called by mutect2, pindel, varscan2
- COL9A2 | c.811G>T p.G271* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101025599; called by muse, mutect2, varscan2
- COLGALT1 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.166); catalogued as rs1413394794, COSV99394862; called by muse, mutect2, varscan2
- COPA | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1252870201, COSV54102114, COSV99614766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS3 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs773256226, COSV52005666; called by mutect2, varscan2
- COQ8A | c.446C>A p.P149H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100825558; called by muse, mutect2, varscan2
- CORO2B | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs751295241, COSV99962942; called by muse, mutect2
- COX10 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV99886048; called by muse, mutect2
- CPLANE2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as rs1249511161, COSV65056670; called by muse, mutect2, varscan2
- CR1L | c.584del p.K195Rfs*56 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | catalogued as COSV54331368; called by mutect2, pindel, varscan2
- CRACR2B | c.458+2T>C p.X153_splice | Splice Site (SNP) | VAF 8/49 reads (16%) | catalogued as rs781229569, COSV100351955; called by muse, mutect2, varscan2
- CREB3L2 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.023); catalogued as COSV100381624, COSV57792666; called by muse, mutect2, varscan2
- CREBBP | c.2300C>T p.S767F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52119925, COSV99268766; called by muse, mutect2, varscan2
- CRISPLD2 | c.1157-1G>T p.X386_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99295425; called by muse, mutect2, varscan2
- CRMP1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV100271440, COSV61478773; called by muse, mutect2, varscan2
- CROCC | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs369407665, COSV100978073; called by muse, mutect2, varscan2
- CROCC | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV100978074; called by muse, mutect2
- CSF3R | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs765312095, COSV58970039; called by muse, mutect2, varscan2
- CSMD2 | c.10240G>A p.A3414T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1297525234, COSV99586644; called by muse, mutect2, varscan2
- CSN1S1 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs375053260; called by muse, mutect2, varscan2
- CSNK1E | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs1027024602, COSV100724983; called by muse, mutect2, varscan2
- CSTF2 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV65895464; called by muse, mutect2, varscan2
- CTC1 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.121); catalogued as rs201788219, COSV100236177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCR6 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs201299542, COSV99945215; called by muse, mutect2, varscan2
- CXorf58 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs765534922, COSV64858063; called by muse, mutect2, varscan2
- CYB5R3 | c.836T>C p.M279T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99348914; called by muse, mutect2
- CYFIP1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs778294512; called by muse, mutect2, varscan2
- CYP19A1 | c.628+2T>C p.X210_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as rs750338018, COSV99547370; called by muse, mutect2
- CYP27C1 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.394); catalogued as rs1209248467, COSV58867548; called by muse, mutect2, varscan2
- D2HGDH | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344199; called by muse, mutect2
- DACT1 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs147227144; called by muse, mutect2, varscan2
- DAGLB | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99765679; called by muse, mutect2, varscan2
- DAZAP1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99244988; called by muse, mutect2, varscan2
- DCHS1 | c.9593G>A p.R3198H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs139629352; called by muse, mutect2, varscan2
- DCSTAMP | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs143444954, COSV99886134; called by muse, mutect2, varscan2
- DCUN1D5 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99498913; called by muse, mutect2, varscan2
- DDR1 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs151111058; called by muse, mutect2, varscan2
- DEFB113 | c.73del p.T25Qfs*? | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs758917875, COSV104398000; called by mutect2, pindel, varscan2
- DGKH | c.1597A>C p.T533P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99818401; called by muse, mutect2, varscan2
- DHRS12 | c.758G>A p.R253H (on ENST00000444610 / NM_001377930.1; = p.R204H on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1194665679, COSV99523723; called by muse, mutect2
- DHRS2 | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99158790; called by muse, mutect2, varscan2
- DHX30 | c.698A>G p.D233G (on ENST00000445061 / NM_138615.3; = p.D194G on NM_014966.3) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100819957; called by muse, mutect2
- DHX33 | c.1888A>G p.M630V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs199938817, COSV99834242; called by muse, mutect2, varscan2
- DHX9 | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.043); catalogued as COSV62358954; called by muse, mutect2, varscan2
- DICER1 | c.4417del p.S1473Qfs*17 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as COSV58617589; called by mutect2, pindel, varscan2
- DKK3 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV100484929; called by muse, mutect2
- DLGAP2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1304311740, COSV101421108; called by muse, mutect2
- DMWD | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV99536964; called by mutect2, varscan2
- DMXL2 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99195999; called by muse, mutect2
- DNAH1 | c.11768C>T p.P3923L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs760015031, COSV99963483; called by muse, mutect2, varscan2
- DNAH10 | c.8570G>A p.R2857H (on ENST00000409039; = p.R2796H on NM_207437.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs763152052, COSV68994327; called by muse, mutect2, varscan2
- DNAH2 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV99317944; called by muse, mutect2
- DNAH5 | c.7474G>A p.A2492T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54202086, COSV54222629, COSV54234650; called by muse, mutect2, varscan2
- DNAH9 | c.7361C>T p.T2454M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387545453, COSV52363465, COSV52377010; called by muse, mutect2, varscan2
- DNAJA4 | c.488T>C p.I163T (on ENST00000343789; = p.I192T on NM_018602.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as COSV100655128; called by muse, mutect2, varscan2
- DNAJB1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs756147811, COSV99584006; called by muse, mutect2, varscan2
- DNMT3B | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM002946, COSV52415711; called by muse, mutect2
- DOCK11 | c.4145-2A>G p.X1382_splice | Splice Site (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99353040; called by muse, mutect2
- DOCK3 | c.5295C>A p.G1765= | Splice Region (SNP) | VAF 16/121 reads (13%) | catalogued as COSV99809540; called by muse, mutect2, varscan2
- DOCK4 | c.4678G>A p.V1560M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs985782302, COSV101447792; called by muse, mutect2, varscan2
- DOT1L | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745700742, COSV67109155; called by mutect2, varscan2
- DPYSL5 | c.948-2A>G p.X316_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99981841; called by muse, mutect2, varscan2
- DYNC2H1 | c.11135G>A p.R3712H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs756326880, COSV100517687; called by muse, mutect2, varscan2
- DYRK4 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99155456; called by muse, mutect2, varscan2
- EHD2 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99621676; called by muse, mutect2, varscan2
- ELP3 | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs765496547, COSV99833808; called by muse, mutect2, varscan2
- EMILIN1 | c.2136G>T p.E712D | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99565812; called by muse, mutect2
- EP400 | c.8971T>C p.S2991P | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.943); catalogued as COSV100200546; called by muse, mutect2, varscan2
- EPHA3 | c.370T>C p.Y124H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100343279; called by muse, mutect2, varscan2
- ERBIN | c.1305T>C p.D435= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs754163910, COSV99396004; called by muse, mutect2, varscan2
- ETS2 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs1310195239, COSV100711190; called by muse, mutect2, varscan2
- EVC2 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as COSV100185167, COSV60394636; called by muse, mutect2, varscan2
- EVPL | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs759778373, COSV56911713; called by muse, mutect2, varscan2
- EXOC3 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.925); catalogued as COSV100155131; called by muse, mutect2, varscan2
- EXOC3 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1277354266, COSV59266321; called by muse, mutect2, varscan2
- FAAP24 | c.244-2A>G p.X82_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99577099; called by muse, mutect2, varscan2
- FAM160A2 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs749427194, COSV56412570; called by muse, mutect2, varscan2
- FAM160A2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99791761; called by muse, mutect2
- FAM241B | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758997308, COSV100958389; called by muse, mutect2, varscan2
- FAM47A | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100649748; called by mutect2, varscan2
- FAM53B | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV55104148, COSV99784832; called by muse, mutect2, varscan2
- FAM9A | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.437); catalogued as COSV101121307; called by muse, mutect2, varscan2
- FANK1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs768390344, COSV64159091; called by muse, mutect2, varscan2
- FAT2 | c.11584G>A p.A3862T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs747251482, COSV55823165; called by muse, mutect2, varscan2
- FBN3 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs757123409, COSV54459400; called by muse, mutect2, varscan2
- FCHSD2 | c.1909T>C p.W637R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100237959; called by muse, mutect2, varscan2
- FCRL1 | c.1054del p.Q352Kfs*21 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | catalogued as COSV63828138; called by mutect2, pindel, varscan2
- FCSK | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs767472330, COSV99850546; called by muse, mutect2, varscan2
- FER1L6 | c.1427del p.N476Mfs*15 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs757073355; called by mutect2, pindel, varscan2
- FGF3 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV100490096; called by muse, mutect2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFBP3 | c.760A>G p.N254D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100284602; called by muse, mutect2, varscan2
- FHOD1 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1159287570, COSV99263882; called by muse, mutect2, varscan2
- FILIP1 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538214169, COSV52728066; called by mutect2, varscan2
- FIP1L1 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100184240; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FKBPL | c.231_232del p.H78* | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs756512778; called by pindel, varscan2
- FLII | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100493456; called by muse, mutect2, varscan2
- FLNA | c.5173C>T p.R1725C (on ENST00000369850 / NM_001110556.2; = p.R1717C on NM_001456.3) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1195468267, COSV100774325; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as COSV56098414; called by mutect2, pindel, varscan2
- FN1 | c.3424G>A p.G1142S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1359530623, COSV100116263, COSV60550169; called by muse, mutect2, varscan2
- FOSB | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100798699; called by muse, mutect2, varscan2
- FOXP2 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs745987986, COSV63484878; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.755); catalogued as rs779542189, COSV58544526, COSV58565442; called by muse, mutect2, varscan2
- FREM1 | c.5578T>C p.S1860P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV101083896; called by muse, mutect2, varscan2
- FREM1 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs756520564, COSV66518660; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs752538869; called by pindel, varscan2
- FRMD4A | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs1564626656, COSV99198408; called by muse, mutect2, varscan2
- FRMPD3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs1434750366, COSV99345448; called by muse, mutect2, varscan2
- FSHR | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.997); catalogued as COSV100436635; called by muse, mutect2, varscan2
- FZD10 | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as COSV57472509, COSV99969269; called by muse, mutect2, varscan2
- GABBR1 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as rs147560335; called by muse, mutect2, varscan2
- GABRA3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs139179813, COSV64799220; called by muse, mutect2, varscan2
- GAK | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs774959451, COSV100033202; called by muse, mutect2, varscan2
- GAL3ST1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.767); catalogued as rs1198228615, COSV100142932; called by muse, mutect2, varscan2
- GALP | c.153A>T p.Q51H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100627865; called by muse, mutect2, varscan2
- GAPDH | c.586_587del p.W196Afs*2 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs778058544; called by pindel, varscan2
- GBA3 | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV72438089; called by muse, mutect2, varscan2
- GDF6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as rs866512501, COSV99747693; called by muse, mutect2, varscan2
- GDPD5 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs760292424, COSV100409110; called by muse, mutect2, varscan2
- GEMIN5 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99593623; called by muse, mutect2, varscan2
- GEMIN6 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV99931551; called by muse, mutect2, varscan2
- GFOD2 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52059948; called by muse, mutect2, varscan2
- GFRAL | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100474685; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as rs750227570; called by mutect2, varscan2
- GLB1 | c.2006dup p.N669Kfs*53 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | catalogued as rs759633494; called by mutect2, varscan2
- GLI1 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV99953727; called by mutect2, varscan2
- GLI4 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100390920; called by muse, mutect2, varscan2
- GLOD4 | c.338G>A p.S113N (on ENST00000301328 / NM_001366247.1; = p.S98N on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100022431; called by muse, mutect2, varscan2
- GLYATL2 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV99780224; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs749150409; called by mutect2, varscan2
- GNRH1 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99373574; called by muse, mutect2, varscan2
- GPATCH8 | c.2293A>G p.S765G | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100132488; called by muse, mutect2, varscan2
- GPR137B | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100858320; called by muse, mutect2, varscan2
- GPR161 | c.1535G>T p.R512M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV99606278; called by muse, mutect2, varscan2
- GPR162 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs1457517841, COSV99163696; called by muse, mutect2, varscan2
- GPR50 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV54438168; called by muse, mutect2, varscan2
- GPR68 | c.695G>A p.S232N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs969714744, COSV99473381; called by muse, mutect2, varscan2
- GPSM1 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99395844; called by muse, mutect2
- GPX4 | c.563T>A p.V188E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100684151; called by muse, mutect2
- GRIA3 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.993); catalogued as rs747646413, COSV52079590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM5 | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100550488; called by muse, mutect2, varscan2
- GSAP | c.1673A>G p.E558G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as COSV99990001; called by muse, mutect2, varscan2
- GTF2I | c.869T>C p.V290A (on ENST00000573035 / NM_032999.4; = p.V270A on NM_001518.5) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs782819986, COSV100259464; called by muse, mutect2, varscan2
- GTF3C2 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV53125847; called by muse, mutect2
- GUCY2F | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV99484570; called by muse, mutect2, varscan2
- GYS2 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748945649, COSV53926734; called by muse, mutect2, varscan2
- HAND2 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as rs780513534, COSV100854148; called by mutect2, varscan2
- HCAR1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.019); catalogued as COSV100811484; called by muse, mutect2, varscan2
- HCAR3 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs572713524, COSV63679355; called by muse, varscan2
- HCN2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as rs775274951, COSV99241333; called by muse, mutect2, varscan2
- HDAC4 | c.2206A>G p.K736E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.106); catalogued as COSV100612751; called by muse, mutect2, varscan2
- HDGFL2 | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100012124; called by muse, mutect2, varscan2
- HMCN2 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as rs147718700; called by mutect2, varscan2
- HMGCR | c.64G>C p.V22L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV99843054; called by muse, mutect2, varscan2
- HNRNPM | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs1394060360, COSV99725266; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXA7 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762508295, COSV54218376, COSV99636257; called by muse, mutect2, varscan2
- HOXB3 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as rs878940792, COSV100290563; called by muse, mutect2
- HRC | c.2064-1G>T p.X688_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99417577; called by muse, mutect2, varscan2
- HSPG2 | c.3428G>A p.G1143D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101020452; called by muse, mutect2, varscan2
- ICMT | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100658218; called by muse, mutect2, varscan2
- IFRD1 | c.907-2A>G p.X303_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99133650; called by muse, mutect2, varscan2
- IGF1R | c.3508G>T p.G1170W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99149110; called by muse, mutect2, varscan2
- IGF2BP1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as rs531902165, COSV99288311; called by muse, mutect2, varscan2
- IGF2BP1 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV99288315; called by muse, mutect2
- IGHV1-46 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as rs782735257; called by muse, mutect2, varscan2
- IGSF10 | c.2426C>A p.P809Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV99176782; called by muse, mutect2, varscan2
- IGSF11 | c.326A>G p.N109S (on ENST00000393775 / NM_001015887.3; = p.N108S on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100677053; called by muse, mutect2, varscan2
- IL1RAP | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299071; called by muse, mutect2, varscan2
- IMPDH1 | c.1316C>T p.A439V (on ENST00000470772 / NM_001142573.2; = p.A525V on NM_000883.4) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs576852864, COSV100118601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INF2 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs200386025, COSV53035909; called by muse, mutect2, varscan2
- INSR | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs745372291, COSV57158199; called by muse, mutect2, varscan2
- IQGAP3 | c.3583A>G p.M1195V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1261888913, COSV100752078; called by muse, mutect2, varscan2
- IRX4 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414647587, COSV51473045, COSV51474566; called by muse, mutect2, varscan2
- ISL1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100045081; called by muse, mutect2
- ITGA2B | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288615; called by muse, mutect2, varscan2
- ITGB8 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs768194871, COSV56004933; called by muse, mutect2, varscan2
- IWS1 | c.1123del p.M375Wfs*15 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs1558756872; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs763256629, COSV54608413; called by muse, mutect2, varscan2
- JMJD1C | c.4667C>T p.T1556I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550173; called by muse, mutect2
- KANSL1 | c.3028C>T p.R1010* (on ENST00000574590 / NM_001193465.2; = p.R1011* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99289853; called by muse, mutect2, varscan2
- KCNE1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as rs372398235; ClinVar: uncertain significance; called by muse, varscan2
- KCNH5 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100525512; called by muse, mutect2
- KCNK4 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs867555217, COSV100487267; called by muse, mutect2, varscan2
- KCNQ2 | c.2051G>A p.G684D (on ENST00000359125 / NM_172107.4; = p.G656D on NM_004518.6) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100609835; called by muse, mutect2, varscan2
- KCNT1 | c.2735A>G p.Q912R (on ENST00000488444; = p.Q931R on NM_020822.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV53696648, COSV99705085; called by muse, mutect2, varscan2
- KDM2B | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555305855, COSV65644275; called by muse, mutect2, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs1561792565; called by mutect2, varscan2
- KDM5C | c.1122G>A p.A374= | Splice Region (SNP) | VAF 6/45 reads (13%) | catalogued as COSV64764634; called by muse, mutect2, varscan2
- KDM8 | c.263A>G p.D88G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV99619274; called by muse, mutect2, varscan2
- KHDC1 | c.233C>T p.T78M (on ENST00000370384 / NM_001251874.2; = p.T5M on NM_030568.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs774462256, COSV100001740; called by muse, mutect2, varscan2
- KIAA0100 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1263665277, COSV66491978; called by muse, mutect2, varscan2
- KIAA0513 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99260502; called by muse, mutect2, varscan2
- KIAA0895L | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1275376669, COSV51783470, COSV99220400; called by muse, mutect2, varscan2
- KIF13B | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779216622, COSV73054633; called by muse, mutect2, varscan2
- KIF14 | c.2307G>T p.W769C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950647; called by muse, mutect2, varscan2
- KIF1C | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759883791, COSV100296978; called by muse, mutect2, varscan2
- KIFC1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100995990, COSV65728500, COSV65729494; called by muse, mutect2, varscan2
- KLF9 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as COSV101009521, COSV65807890; called by mutect2, varscan2
- KLHL3 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.533); catalogued as rs781171421, COSV59051844, COSV59055965; called by muse, mutect2, varscan2
- KLHL8 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99911249; called by muse, mutect2, varscan2
- KLK6 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037622, COSV59565631; called by muse, mutect2
- KMT2B | c.2428C>A p.Q810K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99385874; called by muse, mutect2, varscan2
- KNL1 | c.1466A>G p.Y489C (on ENST00000346991 / NM_170589.5; = p.Y463C on NM_144508.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100706019; called by muse, mutect2, varscan2
- KRT13 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.886); catalogued as rs752191840, COSV99877218; called by muse, mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- KRT40 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770104419, COSV100898772; called by muse, mutect2, varscan2
- KRT76 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs772255928, COSV60118987; called by muse, mutect2, varscan2
- KRT86 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV53293187; called by muse, mutect2, varscan2
- KSR1 | c.1409G>A p.S470N (on ENST00000644974 / NM_001367810.1; = p.S333N on NM_014238.2) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs1298252607, COSV99258348; called by muse, mutect2, varscan2
- LAMA2 | c.7880A>G p.H2627R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV101370158; called by muse, mutect2, varscan2
- LAMA5 | c.6404del p.P2135Rfs*74 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | catalogued as rs1568919861; called by mutect2, pindel, varscan2
- LAMB2 | c.4882del p.A1628Qfs*26 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as COSV59732734; called by mutect2, pindel, varscan2
- LAMB4 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1178892859, COSV99222997; called by muse, mutect2, varscan2
- LGALS12 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs149862322; called by muse, mutect2, varscan2
- LGSN | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101040307; called by mutect2, varscan2
- LIG1 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as rs1052689350, COSV99618568; called by mutect2, varscan2
- LINGO4 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV100764933; called by muse, mutect2, varscan2
- LMNB2 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs746479856, COSV53114022; called by muse, mutect2, varscan2
- LMO7 | c.1892A>T p.Q631L (on ENST00000357063; = p.Q361L on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV100412541; called by muse, mutect2, varscan2
- LMTK2 | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV99806125; called by muse, mutect2, varscan2
- LOXL3 | c.2165T>C p.I722T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV99239483; called by muse, mutect2, varscan2
- LRFN3 | c.49T>A p.S17T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99873151; called by muse, mutect2, varscan2
- LRIG2 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1255431454, COSV100743023; called by muse, mutect2, varscan2
- LRRC7 | c.3586G>A p.V1196I (on ENST00000651989 / NM_001370785.2; = p.V1163I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as rs921438582, COSV50476832; called by muse, mutect2, varscan2
- LRRCC1 | c.1174T>A p.S392T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as COSV100835302; called by mutect2, varscan2
- LRRIQ3 | c.1134del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs751977298; called by mutect2, pindel, varscan2
- LRRK1 | c.2642A>C p.Q881P | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV99437971; called by muse, mutect2
- LRRTM1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV54438041, COSV54444905; called by muse, mutect2, varscan2
- LRWD1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs937924960, COSV52961035; called by muse, mutect2, varscan2
- LTBP1 | c.3274G>A p.G1092R (on ENST00000404816 / NM_206943.4; = p.G766R on NM_000627.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774524181, COSV55379641; called by muse, mutect2, varscan2
- LTBP4 | c.1417C>T p.R473C (on ENST00000308370 / NM_001042544.1; = p.R436C on NM_003573.2) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs111506468, COSV99180573, COSV99192998; called by muse, mutect2, varscan2
- LUC7L | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs1567170273, COSV99551012; called by muse, mutect2, varscan2
- LYPD6B | c.386C>T p.T129M (on ENST00000409029 / NM_001317004.1; = p.T153M on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as rs755730639, COSV54521125; called by muse, mutect2, varscan2
- LYPLAL1 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.967); catalogued as COSV100859676; called by muse, mutect2, varscan2
- LZTR1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs768361273, COSV53150648; called by muse, mutect2, varscan2
- LZTS1 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306731383, COSV99742720; called by muse, mutect2, varscan2
- LZTS3 | c.417C>A p.S139R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100232154; called by muse, mutect2, varscan2
- MAGEA8 | c.856T>C p.Y286H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99674422; called by muse, mutect2, varscan2
- MAGEB1 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100974858; called by muse, mutect2, varscan2
- MAGEE1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs892088909, COSV100819299, COSV63910595; called by muse, mutect2, varscan2
- MAGEF1 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100510913; called by muse, mutect2, varscan2
- MAGEL2 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1249939836, COSV100045758; called by muse, varscan2
- MAOB | c.83T>G p.L28R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100955927; called by muse, mutect2
- MAP1A | c.5242C>T p.R1748W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.406); catalogued as COSV100288165; called by muse, mutect2, varscan2
- MAP1A | c.7942C>T p.R2648C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs758664345, COSV100288167; called by muse, mutect2, varscan2
- MAP1A | c.8191G>A p.E2731K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100288168; called by muse, mutect2, varscan2
- MAP3K1 | c.2253G>A p.W751* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101266306; called by mutect2, varscan2
- MAPK8IP3 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1294092964, COSV99167707; called by muse, mutect2, varscan2
- MASP1 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.163); catalogued as rs1184974017, COSV99396821; called by muse, mutect2, varscan2
- MAST1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773630027, COSV52253946; called by muse, mutect2, varscan2
- MATN4 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 10/31 reads (32%) | PolyPhen probably damaging (1); catalogued as rs761461093, COSV100636900; called by muse, mutect2, varscan2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs748185381; called by mutect2, pindel, varscan2
- MBOAT2 | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100019795; called by muse, mutect2, varscan2
- MCF2L | c.880A>G p.S294G (on ENST00000375608; = p.S262G on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100982158; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCTP1 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1450694472, COSV100386399; called by muse, mutect2, varscan2
- MDGA1 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs746453937, COSV51796966; called by muse, mutect2, varscan2
- MED12 | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs940532752, COSV61339079; called by muse, mutect2, varscan2
- MED12L | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99851739; called by muse, mutect2
- MEF2D | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61729462; called by muse, mutect2, varscan2
- MEFV | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99560336; called by muse, mutect2, varscan2
- MEGF10 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99174739; called by muse, mutect2, varscan2
- MEGF10 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99174742, COSV99175250; called by muse, mutect2, varscan2
- METAP2 | c.668G>A p.C223Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99704678; called by muse, mutect2, varscan2
- MFGE8 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754732007, COSV99183939; called by muse, mutect2, varscan2
- MIA2 | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99697346; called by muse, mutect2, varscan2
- MIS18BP1 | c.470_471del p.K157Ifs*8 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | catalogued as rs546807245; called by mutect2, varscan2
- MKI67 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.312); catalogued as COSV100896209; called by muse, mutect2, varscan2
- MLH1 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs147939838, CD011632, COSV51621039, COSV99212663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP21 | c.1025_1026del p.K342Rfs*13 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | catalogued as rs1487834487; called by mutect2, pindel, varscan2
- MMS19 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs751672463, COSV100512688; called by muse, mutect2, varscan2
- MROH2B | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV101270530; called by muse, mutect2
- MRPL28 | c.222A>T p.E74D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV99170596; called by muse, mutect2, varscan2
- MRPL4 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as rs762855612, COSV53447238; called by muse, mutect2
- MRPL53 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs746411133, COSV99252004; called by mutect2, varscan2
- MSL1 | c.799C>T p.R267W (on ENST00000398532 / NM_001365919.1; = p.R4W on NM_001012241.2) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs752605542, COSV100278022; called by muse, mutect2, varscan2
- MST1 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs191996618; called by muse, mutect2, varscan2
- MTF1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100888580; called by muse, mutect2, varscan2
- MTHFD1 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs111509453, COSV99386594; called by muse, mutect2, varscan2
- MTMR3 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs755138094, COSV60305500; called by muse, mutect2, varscan2
- MUC16 | c.35803T>C p.S11935P | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.046); catalogued as COSV101198368; called by muse, mutect2, varscan2
- MUC5B | c.9074T>C p.L3025P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.193); catalogued as COSV101500057; called by muse, mutect2, varscan2
- MUC6 | c.4232C>A p.T1411K | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.072); catalogued as rs368570174, COSV70133860; called by muse, varscan2
- MUC6 | c.4231A>T p.T1411S | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs539991600, COSV70144458; called by muse, varscan2
- MYBL2 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99406039; called by muse, mutect2, varscan2
- MYC | c.71A>G p.Y24C (on ENST00000377970; = p.Y39C on NM_002467.6) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99419467; called by muse, mutect2, varscan2
- MYH10 | c.3074T>C p.L1025S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV99344254; called by muse, mutect2, varscan2
- MYH11 | c.348G>A p.T116= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as rs781275376, COSV55549213; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH15 | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99842385; called by muse, mutect2, varscan2
- MYH4 | c.2438_2439del p.E813Vfs*48 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs1380445354; called by pindel, varscan2
- MYH9 | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99337974; called by muse, mutect2, varscan2
- MYO18B | c.2099T>C p.L700P | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122754; called by muse, mutect2
- MYO1E | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99894578; called by muse, mutect2, varscan2
- MYO1G | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1349062821, COSV99348502; called by muse, mutect2, varscan2
- MYO7A | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as rs782189807, CD114223, COSV101289053; called by muse, mutect2, varscan2
- MYOM3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs1241256116, COSV100292536; called by muse, mutect2, varscan2
- MYOZ1 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63772512; called by mutect2, varscan2
- NAA16 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769875149, COSV65127991; called by muse, mutect2, varscan2
- NALCN | c.5165G>A p.R1722Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.093); catalogued as rs750952585, COSV99213254; called by muse, mutect2
- NBEA | c.4345A>C p.S1449R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100077209; called by mutect2, varscan2
- NCAPH | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs775388261, COSV99545573; called by muse, mutect2, varscan2
- NCKAP1L | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV99514544, COSV99514579; called by muse, mutect2, varscan2
- NCOR1 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1379969902, COSV51963652, COSV51980479, COSV51988436; called by muse, mutect2, varscan2
- NDUFB11 | c.356G>A p.R119H (on ENST00000377811 / NM_001135998.3; = p.R129H on NM_019056.6) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs782460503, COSV52102129; called by muse, mutect2
- NDUFS2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1452781166, COSV57156161; called by muse, mutect2, varscan2
- NEMF | c.2843T>C p.V948A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100027427; called by muse, mutect2, varscan2
- NEURL4 | c.3794A>G p.Q1265R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100222715; called by mutect2, varscan2
- NGEF | c.716T>G p.I239S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.462); catalogued as COSV99888180; called by muse, varscan2
- NGEF | c.660del p.E221Rfs*72 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV50914474; called by pindel, varscan2
- NHLRC3 | c.263T>G p.L88* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100612663; called by muse, mutect2, varscan2
- NISCH | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1325936211, COSV61899298; called by muse, mutect2, varscan2
- NKTR | c.4064G>T p.R1355I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99235261; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRC3 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs755710065, COSV100072494, COSV57095343; called by muse, mutect2, varscan2
- NLRC5 | c.1202G>C p.S401T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV99346586; called by muse, mutect2
- NLRP3 | c.2300G>A p.G767D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV100275337, COSV60227718; called by muse, varscan2
- NME1-NME2 | c.667G>A p.V223M (on ENST00000555572; = p.V198M on NM_001018136.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs757730632, COSV64510992; called by muse, mutect2, varscan2
- NOC3L | c.1708+2T>C p.X570_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV64930158; called by muse, varscan2
- NOL6 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1466956849, COSV99954489; called by muse, mutect2, varscan2
- NOLC1 | c.1715A>G p.K572R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs756458873, COSV64180375; called by muse, mutect2, varscan2
- NONO | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1016039382, COSV99338615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOSTRIN | c.1220del p.L407* (on ENST00000317647 / NM_001039724.4; = p.L329* on NM_052946.3) | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1258179126; called by mutect2, pindel, varscan2
- NOTCH1 | c.5717C>T p.A1906V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as rs756056361, COSV99485755; called by muse, mutect2, varscan2
- NOTCH3 | c.897C>A p.S299R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.817); catalogued as COSV99656072; called by muse, mutect2, varscan2
- NR1D2 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100437301; called by muse, mutect2, varscan2
- NR4A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs201350514, COSV100276947; called by muse, varscan2
- NR5A2 | c.782A>G p.Y261C (on ENST00000367362 / NM_205860.3; = p.Y215C on NM_003822.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV99370720; called by muse, mutect2
- NRK | c.3739C>T p.R1247* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99686727; called by muse, mutect2, varscan2
- NRROS | c.1358del p.P453Lfs*12 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs1287233013; called by mutect2, pindel, varscan2
- NSF | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV99833691; called by muse, mutect2
- NSMAF | c.2377A>G p.T793A | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99232407; called by muse, mutect2, varscan2
- NSUN2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as rs746566794, COSV99242994; called by mutect2, varscan2
- NTRK2 | c.971T>C p.L324S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99452839; called by muse, mutect2, varscan2
- NUBPL | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs886050449, COSV99809121; ClinVar: uncertain significance; called by muse, mutect2
- NYNRIN | c.2584C>T p.L862F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101230513; called by muse, mutect2, varscan2
- OAZ1 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); catalogued as COSV100457251; called by muse, mutect2, varscan2
- OBSCN | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs374032777; called by muse, mutect2, varscan2
- OLFM2 | c.455_457del p.E152del | In Frame Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1331569897; called by pindel, varscan2
- OLFML2A | c.1402G>T p.G468C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56585170; called by muse, mutect2
- OLFML2B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs779770482, COSV54197630; called by muse, mutect2, varscan2
- OPA1 | c.2228C>T p.P743L (on ENST00000361510 / NM_130837.3; = p.P688L on NM_015560.3) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs746579947, COSV62479825; called by mutect2, varscan2
- OPCML | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770223558, COSV59410726; called by muse, mutect2, varscan2
- OR11H6 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1360414444, COSV100209722; called by muse, mutect2, varscan2
- OR2A14 | c.282del p.P95Hfs*3 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as COSV68718098; called by mutect2, pindel, varscan2
- OR2AK2 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100822921; called by muse, mutect2, varscan2
- OR2M2 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs568153469, COSV100677184; called by muse, mutect2, varscan2
- OR2T33 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | catalogued as COSV100531646; called by muse, mutect2, varscan2
- OR4Q3 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100056746; called by muse, mutect2, varscan2
- OR6B1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV101281633, COSV101281654; called by muse, mutect2, varscan2
- OR8B2 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.024); catalogued as COSV100899330; called by muse, mutect2, varscan2
- OR8H3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771350543, COSV57908542; called by muse, mutect2, varscan2
- ORAI2 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs771911609, COSV100709851; called by muse, mutect2, varscan2
- OSBPL10 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1255623403, COSV67337708; called by muse, mutect2, varscan2
- OSBPL1A | c.1823C>T p.A608V (on ENST00000319481 / NM_080597.4; = p.A95V on NM_018030.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.625); catalogued as rs750232865, COSV60194785; called by muse, mutect2, varscan2
- OSCP1 | c.778A>G p.M260V (on ENST00000356637 / NM_001330493.1; = p.M250V on NM_145047.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV99347046; called by muse, mutect2, varscan2
- OTOGL | c.6335A>G p.K2112R (on ENST00000547103; = p.K2103R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.996); catalogued as COSV100086764; called by muse, mutect2, varscan2
- OTUB2 | c.304-1G>T p.X102_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99180145, COSV99180154, COSV99180159; called by muse, mutect2, varscan2
- OTUD3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs770547354, COSV64296164; called by mutect2, varscan2
- PACC1 | c.488A>G p.Q163R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV99800796; called by muse, mutect2, varscan2
- PACRG | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.223); catalogued as COSV100433346; called by muse, mutect2, varscan2
- PAEP | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); catalogued as rs754340819, COSV99478855; called by muse, mutect2, varscan2
- PALD1 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as rs1356675362, COSV99698008; called by muse, mutect2, varscan2
- PARD3B | c.3586C>T p.R1196W (on ENST00000406610 / NM_001302769.2; = p.R1127W on NM_057177.7) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs888272675, COSV100592272; called by muse, mutect2, varscan2
- PCDH15 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs747154146, COSV57374587; called by muse, mutect2, varscan2
- PCDH17 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.787); catalogued as COSV100931455; called by muse, mutect2, varscan2
- PCDHA6 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV100972135; called by muse, mutect2, varscan2
- PCDHA9 | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV65324163; called by muse, mutect2, varscan2
- PCDHB15 | c.2218A>T p.S740C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV99178828; called by muse, mutect2, varscan2
- PCDHB7 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99175947; called by muse, mutect2, varscan2
- PCDHB9 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs370384637; called by muse, mutect2, varscan2
- PCDHB9 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.517); catalogued as COSV53375107; called by muse, mutect2, varscan2
- PCDHGA12 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs1328476453, COSV52752192; called by muse, mutect2, varscan2
- PCDHGA3 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV99531956; called by muse, mutect2, varscan2
- PCDHGB1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs755575621, COSV99531958; called by muse, mutect2, varscan2
- PCDHGB6 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV53992311; called by muse, mutect2, varscan2
- PCDHGC4 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374901235; called by muse, mutect2, varscan2
- PCF11 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs370476007; called by muse, mutect2, varscan2
- PCF11 | c.2671T>C p.F891L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100017872; called by muse, mutect2, varscan2
- PCGF1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99283191; called by muse, mutect2, varscan2
- PCNT | c.9629G>A p.R3210H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779541254, COSV100855085; called by muse, mutect2, varscan2
- PCNX2 | c.1459del p.R487Gfs*55 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | catalogued as COSV50858387; called by mutect2, pindel, varscan2
- PCSK2 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99358800; called by muse, mutect2
- PCSK7 | c.1824G>C p.W608C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402516382, COSV99638943; called by muse, mutect2, varscan2
- PCYOX1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037064; called by muse, mutect2, varscan2
- PDCD11 | c.4874A>G p.Y1625C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367231955, COSV99588270; called by muse, mutect2, varscan2
- PDHA1 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100870215, COSV63328813; called by muse, mutect2, varscan2
- PDZD8 | c.3128T>C p.L1043P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100041378; called by muse, mutect2, varscan2
- PER2 | c.2719A>G p.M907V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99611491; called by muse, mutect2
- PES1 | c.676T>C p.F226L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV100072989; called by muse, mutect2, varscan2
- PFKL | c.2098T>C p.F700L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100297108; called by muse, mutect2
- PGBD5 | c.475G>A p.G159R (on ENST00000525115; = p.G228R on NM_001258311.2) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.963); catalogued as rs367880375, COSV58413150; called by muse, mutect2, varscan2
- PHKA1 | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs140865522, COSV59801883; called by muse, mutect2, varscan2
- PHRF1 | c.460T>C p.C154R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52751429, COSV99199579; called by muse, mutect2, varscan2
- PHTF2 | c.2234T>C p.L745S (on ENST00000248550 / NM_001366089.1; = p.L707S on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99301157; called by muse, mutect2, varscan2
- PIGV | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.059); catalogued as COSV99314769; called by muse, mutect2, varscan2
- PIK3C3 | c.1319T>C p.I440T | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100010446; called by muse, mutect2
- PITPNM2 | c.3688G>A p.V1230M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1402049148, COSV54906780; called by muse, mutect2, varscan2
- PITPNM2 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99758393; called by muse, mutect2, varscan2
- PKD1 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.729); catalogued as COSV99237273; called by muse, mutect2, varscan2
- PKDREJ | c.4477C>T p.H1493Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs984755779, COSV99478481; called by muse, mutect2, varscan2
- PKN1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs371885982; called by muse, mutect2, varscan2
- PKP1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs377328987, COSV99825533; called by muse, mutect2, varscan2
- PLA2G4E | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs987563808, COSV101268532; called by muse, mutect2, varscan2
- PLA2G4F | c.1782C>T p.D594= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs757827731, COSV99300365; called by muse, varscan2
- PLAU | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101032257; called by muse, mutect2, varscan2
- PLBD2 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs529862419, COSV99785205; called by mutect2, varscan2
- PLCB1 | c.3086A>G p.Y1029C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1188524170, COSV100569544; called by muse, mutect2, varscan2
- PLCD3 | c.1904G>A p.G635D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364620; called by muse, mutect2, varscan2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG5 | c.1763T>C p.V588A (on ENST00000400915 / NM_001042663.3; = p.V551A on NM_020631.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100556196, COSV61067665; called by muse, mutect2
- PLEKHG5 | c.1502C>T p.T501M (on ENST00000400915 / NM_001042663.3; = p.T464M on NM_020631.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777612808, COSV61069727; called by mutect2, varscan2
- PLIN4 | c.1264G>A p.V422I (on ENST00000301286; = p.V437I on NM_001367868.2) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs536634451, COSV100012798, COSV56691251; called by muse, mutect2
- PLRG1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100122988; called by muse, mutect2, varscan2
- PLXNA1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1199026244, COSV99302394; called by muse, mutect2, varscan2
- PML | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as rs1384418899, COSV99166715; called by muse, mutect2, varscan2
- PMS2 | c.1239del p.D414Tfs*34 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as CD040607; called by mutect2, varscan2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | catalogued as rs781891121, COSV61745231; called by mutect2, pindel
- POLK | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99605594; called by muse, mutect2, varscan2
- POLRMT | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775563440, COSV52112005; called by muse, mutect2, varscan2
- POM121 | c.2197A>G p.T733A (on ENST00000434423; = p.T468A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV99987686; called by muse, mutect2
- POSTN | c.1393-1G>T p.X465_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as COSV101123255; called by muse, mutect2, varscan2
- PPIL4 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV53567282; called by mutect2, varscan2
- PPM1M | c.32G>A p.S11N (on ENST00000296487; = p.S172N on NM_144641.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.161); catalogued as COSV99626049; called by muse, mutect2, varscan2
- PPP1R15A | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as rs775150021, COSV99565853; called by muse, mutect2, varscan2
- PPP1R26 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs756321419, COSV63354623; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | catalogued as rs758484975; called by mutect2, varscan2
- PPP6C | c.171G>A p.Q57= | Splice Region (SNP) | VAF 6/23 reads (26%) | catalogued as rs1275605390, COSV65209472; called by muse, mutect2, varscan2
- PRAME | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as rs770764905, COSV101287020; called by muse, mutect2, varscan2
- PRDM4 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747069656, COSV57305387; called by muse, mutect2
- PRG4 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825639; called by muse, mutect2
- PRMT5 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.474); catalogued as COSV99362781; called by muse, mutect2, varscan2
- PRSS48 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as rs775385056, COSV71613582; called by muse, mutect2, varscan2
- PRX | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV99397506; called by muse, mutect2, varscan2
- PSMB7 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as rs369427242; called by muse, mutect2, varscan2
- PTGIR | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs767052852, COSV99354900; called by muse, varscan2
- PTPN13 | c.6578C>T p.T2193M (on ENST00000411767 / NM_080683.3; = p.T2174M on NM_006264.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs778543538, COSV57404319; called by muse, mutect2, varscan2
- PTPN21 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1461721444, COSV100161558, COSV100161857; called by muse, mutect2
- PTPN21 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1375707004, COSV100161561; called by muse, mutect2, varscan2
- PTPN6 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375296528; called by muse, mutect2, varscan2
- PTPRF | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs776883780, COSV100740666; called by muse, mutect2, varscan2
- PTPRM | c.3747C>T p.D1249= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs552851512, COSV59883677; called by mutect2, varscan2
- PTPRR | c.1360-1G>T p.X454_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99316442; called by muse, mutect2, varscan2
- PUM3 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs62534389, COSV67396307; called by muse, mutect2, varscan2
- PUS7 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100708451, COSV62677010; called by muse, mutect2, varscan2
- PXDN | c.3572A>G p.E1191G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs558567423, COSV99412456; called by muse, mutect2, varscan2
- PZP | c.2999A>T p.Q1000L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV99736475; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs755727862; called by mutect2, varscan2
- QRICH1 | c.1375T>C p.S459P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100676679; called by muse, mutect2
- RAB27A | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs151048993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RABGAP1L | c.2348C>T p.T783I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.57); catalogued as COSV99268113; called by muse, mutect2, varscan2
- RAC1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); catalogued as COSV61823416; called by muse, mutect2, varscan2
- RAD1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV100337560; called by muse, mutect2, varscan2
- RAD17 | c.1471A>G p.R491G (on ENST00000380774 / NM_133339.2; = p.R480G on NM_002873.1) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs148563193, COSV51459741; called by mutect2, varscan2
- RAD21 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV52059569, COSV99814845; called by muse, mutect2, varscan2
- RAD54L2 | c.2725T>G p.F909V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.63); catalogued as COSV99620805; called by muse, mutect2
- RAD54L2 | c.3320C>T p.T1107M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs763516756, COSV56578666, COSV99620806; called by muse, mutect2
- RADIL | c.1286del p.G429Afs*6 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as rs768989877; called by mutect2, pindel, varscan2
- RADIL | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.079); catalogued as rs530494594, COSV101271272, COSV68204552; called by muse, mutect2, varscan2
- RALYL | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV72820118; called by muse, mutect2, varscan2
- RANBP10 | c.1379A>C p.E460A | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.309); catalogued as COSV100449139; called by muse, mutect2
- RAPGEF6 | c.1151A>G p.E384G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV57241104, COSV57243737; called by muse, mutect2, varscan2
- RASAL2 | c.1507A>T p.T503S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV100862430; called by muse, mutect2, varscan2
- RASL11A | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99610960, COSV99610998; called by muse, mutect2, varscan2
- RASSF2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as rs745819966, COSV65083428; called by muse, mutect2, varscan2
- RB1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs771421892, COSV99923387; called by muse, mutect2, varscan2
- RBBP6 | c.4155A>G p.I1385M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs779589665, COSV100154264; called by muse, mutect2, varscan2
- RBM27 | c.1925T>C p.L642P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99505758; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RBMX | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs770292839, COSV100284557, COSV100284689; called by muse, mutect2, varscan2
- RELT | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1043037369, COSV50363200, COSV99292682; called by muse, mutect2
- RER1 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99991986; called by muse, mutect2, varscan2
- RETREG2 | c.1282G>T p.G428* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99811396; called by muse, mutect2, varscan2
- RFC1 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100567466; called by muse, mutect2, varscan2
- RHBDL2 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs865873988, COSV56707922; called by muse, mutect2, varscan2
- RHD | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM158944, COSV100154915; called by muse, mutect2
- RHOBTB2 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1055437847, COSV52393697, COSV99310739; called by muse, mutect2, varscan2
- RHOJ | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100370111; called by muse, mutect2, varscan2
- RLBP1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs369127471; called by muse, mutect2, varscan2
- RNF144B | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99464273; called by muse, mutect2, varscan2
- RNF150 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100152996; called by muse, mutect2, varscan2
- ROBO2 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs565768356, COSV59908830; called by muse, mutect2, varscan2
- ROCK1 | c.2156del p.K719Sfs*2 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | catalogued as rs1444380583; called by pindel, varscan2
- RPL35 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as COSV100780829; called by mutect2, varscan2
- RPS6KC1 | c.3168del p.F1056Lfs*9 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as COSV65302116; called by mutect2, pindel, varscan2
- RREB1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.714); catalogued as rs147528961, COSV100619792; called by muse, mutect2, varscan2
- RRP1B | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100512870; called by muse, mutect2, varscan2
- RRP36 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760969484, COSV99763582; called by muse, mutect2, varscan2
- RSF1 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV100406932; called by muse, mutect2, varscan2
- RSF1 | c.1158del p.K386Nfs*6 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1451848162, COSV100408029; called by pindel, varscan2
- RSKR | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as rs140792414; called by muse, mutect2, varscan2
- RTCB | c.1460A>G p.D487G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV53278950; called by muse, mutect2, varscan2
- RTL9 | c.3809T>C p.L1270P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101511637; called by muse, mutect2, varscan2
- RUFY3 | c.572G>T p.S191I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV99886928; called by muse, mutect2
- RYR1 | c.9772G>A p.E3258K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as rs754431075, COSV100614713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs749201569; called by mutect2, varscan2
- SAMM50 | c.1048A>C p.M350L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV100601249, COSV104415149; called by muse, mutect2, varscan2
- SAPCD2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs61746617, COSV68836793; called by muse, mutect2
- SATB1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100112959; called by muse, mutect2, varscan2
- SCN1B | c.641T>A p.V214D | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99384882; called by muse, mutect2, varscan2
- SCUBE1 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs201677167, COSV100682918; called by muse, mutect2, varscan2
- SCYL3 | c.2218A>G p.N740D (on ENST00000367770; = p.N686D on NM_020423.7) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs768787209, COSV99609461; called by muse, varscan2
- SETBP1 | c.2975A>G p.H992R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as COSV99952231; called by muse, mutect2, varscan2
- SFMBT2 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs750153697, COSV100738479; called by muse, mutect2, varscan2
- SH2D3C | c.1571G>T p.R524M (on ENST00000314830 / NM_170600.3; = p.R367M on NM_005489.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV59121622; called by muse, mutect2, varscan2
- SHANK2 | c.3437C>T p.P1146L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1314340729, COSV53598195, COSV53600746; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SIAH2 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs765846031, COSV57261996; called by muse, mutect2, varscan2
- SIK3 | c.1295T>C p.V432A (on ENST00000445177 / NM_001366686.2; = p.V438A on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV99407307; called by mutect2, varscan2
- SIPA1L3 | c.4337_4339del p.F1446del | In Frame Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs771827295; called by pindel, varscan2
- SLAMF1 | c.719T>C p.V240A | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV99348984; called by muse, mutect2, varscan2
- SLC10A3 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); catalogued as COSV99682021; called by muse, mutect2, varscan2
- SLC13A4 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1306234161, COSV62460030; called by muse, mutect2
- SLC24A1 | c.1325del p.P442Qfs*21 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as rs774410891; called by mutect2, pindel, varscan2
- SLC25A43 | c.422A>G p.E141G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV99474429; called by muse, mutect2, varscan2
- SLC35G3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.137); catalogued as rs766443809, COSV52010812; called by muse, mutect2, varscan2
- SLC40A1 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99656161; called by muse, mutect2
- SLC4A2 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.237); catalogued as COSV100054898; called by muse, mutect2, varscan2
- SLC6A11 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594091; called by muse, mutect2
- SLC6A19 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1054432699, COSV100443263; called by muse, mutect2, varscan2
- SLCO3A1 | c.1843G>A p.V615I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs375733540; called by muse, mutect2, varscan2
- SLU7 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99775467; called by muse, mutect2
- SLX4 | c.3962C>T p.P1321L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs778781581, COSV99567651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD6 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993933; called by muse, mutect2, varscan2
- SMAGP | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV101199373; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 11/20 reads (55%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCA2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100570407, COSV61808066; called by muse, mutect2, varscan2
- SMG5 | c.18dup p.T7Hfs*15 | Frame Shift Ins (INS) | VAF 37/132 reads (28%) | catalogued as rs767300459; called by mutect2, varscan2
- SNAP25 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.254); catalogued as COSV99654551; called by muse, mutect2, varscan2
- SNRNP70 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99672193; called by muse, mutect2
- SOCS2 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs142112015, COSV100500019; called by muse, mutect2, varscan2
- SOCS6 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as rs1299589831, COSV101205657; called by muse, varscan2
- SOHLH2 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs1212664892, COSV101157810; called by muse, varscan2
- SOX5 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.995); catalogued as COSV100506128; called by muse, mutect2, varscan2
- SP4 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035233438, COSV56027325; called by muse, mutect2, varscan2
- SPATA6L | c.669+1G>A p.X223_splice (on ENST00000461761 / NM_001353484.2; = p.X165_splice on NM_001039395.4 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as rs146006961, COSV99794835; called by muse, mutect2, varscan2
- SPEF2 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100606439; called by mutect2, varscan2
- SPEG | c.3866C>T p.P1289L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs769975549, COSV56677870; called by muse, mutect2, varscan2
- SPEN | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100402825; called by muse, mutect2
- SPRING1 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99732218; called by muse, mutect2
- SPTA1 | c.4106del p.K1369Sfs*7 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1161647781; called by mutect2, pindel, varscan2
- SPTA1 | c.1249-2A>C p.X417_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100934417, COSV63750778; called by muse, mutect2, varscan2
- SPTBN1 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100441916; called by muse, mutect2
- SPTBN1 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.285); catalogued as COSV100441920; called by muse, mutect2
- SPTBN4 | c.1064G>A p.C355Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100150139; called by muse, mutect2, varscan2
- SRCAP | c.8291T>C p.V2764A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV99349416; called by muse, mutect2, varscan2
- SREBF1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs529689353, COSV55419487, COSV99888482; called by muse, mutect2, varscan2
- SREBF1 | c.1601G>A p.S534N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1280728348, COSV99888380; called by muse, mutect2, varscan2
- SSH2 | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99281506, COSV99283110; called by muse, mutect2, varscan2
- STAB2 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185672; called by muse, mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 11/99 reads (11%) | catalogued as rs746501298; called by mutect2, varscan2
- STEAP1 | c.472A>C p.M158L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV99787542; called by muse, mutect2, varscan2
- STK11IP | c.458G>A p.G153D | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479673507, COSV99822314; called by muse, mutect2
- STMN4 | c.132G>A p.W44* (on ENST00000265770 / NM_001283054.2; = p.W71* on NM_030795.4) | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99740602; called by muse, mutect2, varscan2
- STPG2 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV99758187; called by muse, mutect2, varscan2
- STX10 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs574785224, COSV99456797; called by muse, mutect2, varscan2
- STXBP5 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as COSV51660319; called by muse, mutect2, varscan2
- SULT6B1 | c.537G>T p.W179C (on ENST00000535679 / NM_001367551.1; = p.W141C on NM_001032377.2) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99573020; called by muse, mutect2
- SYNJ1 | c.3422C>A p.P1141H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV100448977; called by muse, mutect2
- SYNPO | c.2582C>T p.S861L (on ENST00000394243 / NM_001166208.2; = p.S617L on NM_007286.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs769668183, COSV100301903; called by muse, mutect2, varscan2
- TAB2 | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644554; called by muse, mutect2, varscan2
- TAF1 | c.4760A>G p.Y1587C (on ENST00000373790 / NM_138923.4; = p.Y1608C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV99334658; called by muse, mutect2, varscan2
- TAF11 | c.408+1G>A p.X136_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as rs1340533231, COSV99511526; called by muse, mutect2, varscan2
- TAF4B | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV99299808; called by muse, mutect2, varscan2
- TAS1R2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1353358849, COSV100946143; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D24 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs773916549, COSV53548182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D9 | c.3571C>T p.R1191W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.586); catalogued as rs777765891, COSV71306948; called by muse, mutect2, varscan2
- TBX3 | c.2168G>T p.S723I (on ENST00000257566 / NM_016569.4; = p.S703I on NM_005996.4) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99983410; called by muse, mutect2, varscan2
665 further variants in this file (274 protein-altering or splice-affecting, 355 silent, 36 other) are not listed here.
